Somatic mutation profile of tumor specimen TCGA-MX-A5UG-01A (aliquot TCGA-MX-A5UG-01A-21D-A31L-08) from TCGA case TCGA-MX-A5UG, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 78.6 years (28,714 days).
Specimen TCGA-MX-A5UG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4951cec9-0109-4fc5-8959-faa8dff38f6c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MX-A5UG-10A (Blood Derived Normal), aliquot TCGA-MX-A5UG-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41f13891-6f87-4e9d-b7de-7f343449006a

The open-access MAF lists 34 somatic variants for this specimen: 27 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 25, Silent 7, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.863A>T p.D288V | Missense Mutation (SNP) | VAF 10/90 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55731893; called by muse, mutect2, varscan2
- ACTL8 | c.713A>G p.Y238C | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV100958463; called by muse, mutect2, varscan2
- ANKRD12 | c.3401A>G p.K1134R | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.985); catalogued as COSV50826999; called by muse, mutect2
- ANKRD28 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV101080196; called by muse, mutect2
- API5 | c.325+2T>G p.X109_splice | Splice Site (SNP) | VAF 3/49 reads (6%) | catalogued as COSV101124491; called by muse, mutect2
- APOB | c.11921C>T p.A3974V | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs762783264, COSV51931475; called by muse, mutect2
- BBX | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs912087215, COSV100360798; called by muse, mutect2
- FOXO1 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65425906; called by muse, mutect2, varscan2
- FOXP2 | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 6/141 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as rs867418322, COSV100646099; called by muse, mutect2
- FREM2 | c.7483C>T p.L2495F | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV99746185; called by mutect2, varscan2
- FSTL4 | c.805A>C p.T269P | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99530959; called by muse, mutect2
- KPNA5 | c.1512C>G p.Y504* | Nonsense Mutation (SNP) | VAF 8/96 reads (8%) | catalogued as COSV100706039; called by muse, mutect2
- LIN28B | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 13/205 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV100558466, COSV61498275; called by muse, mutect2
- LRRTM1 | c.172A>T p.T58S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.345); catalogued as COSV99701602; called by muse, mutect2, varscan2
- MSN | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs746950857, COSV100814045; called by muse, mutect2, varscan2
- NKAP | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57630392; called by muse, mutect2
- OR6C3 | c.699G>T p.K233N | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV65570912; called by muse, mutect2
- PCDH15 | c.3676G>A p.D1226N | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100213520; called by muse, mutect2
- POLB | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99612370; called by muse, mutect2
- RBM19 | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758124511, COSV99925384; called by muse, mutect2
- SLITRK2 | c.1324A>T p.M442L | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV100157259; called by muse, mutect2
- SNCAIP | c.2486G>A p.S829N | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV54425073; called by muse, mutect2, varscan2
- SYNGAP1 | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.383); catalogued as COSV99537700; called by muse, mutect2
- TRIP12 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.019); catalogued as rs1006814717, COSV52260806; called by muse, mutect2
- UNC5D | c.480C>G p.N160K | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99771268; called by muse, mutect2
- ZFP14 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 9/202 reads (4%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.753); catalogued as rs1426790074, COSV54201142; called by muse, mutect2
- ZNF221 | c.653G>A p.R218K | Missense Mutation (SNP) | VAF 11/218 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs1353243783, COSV52108970, COSV52109329, COSV99240507; called by muse, mutect2
- ARRB2 | c.744C>G p.A248= | Silent (SNP) | VAF 10/191 reads (5%) | catalogued as rs1041792430, COSV99346905; called by muse, mutect2
- CACNA1F | c.2223C>T p.L741= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs1557108976, COSV100544241; called by muse, mutect2, varscan2
- EDIL3 | c.453A>C p.G151= | Silent (SNP) | VAF 10/109 reads (9%) | catalogued as COSV99673880; called by muse, mutect2
- IGKV1D-43 | c.42G>T p.L14= | Silent (SNP) | VAF 9/137 reads (7%) | called by muse, mutect2
- PCDHA13 | c.2076G>A p.A692= | Silent (SNP) | VAF 8/116 reads (7%) | catalogued as rs782177968, COSV56494179; called by muse, mutect2
- PI15 | c.138A>G p.A46= | Silent (SNP) | VAF 16/129 reads (12%) | catalogued as COSV99477736; called by muse, mutect2, varscan2
- STAC | c.360C>T p.F120= | Silent (SNP) | VAF 10/149 reads (7%) | catalogued as rs62246671, COSV99829264; called by muse, mutect2
